CCDI case PANLMU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/a282bc6c-1234-467d-8d9c-d3f8add6be4f

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Biospecimens (3 samples)
- Sample 0DHY31: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DHY3S: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DHY47: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
